FM case AD12711 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/214cac38-ddb4-40ec-b884-f5992e608d71

Male, 65.5 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the peritoneum. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
